Gene-level copy-number profile of tumor specimen C3L-06427-03 from CPTAC case C3L-06427, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 79.5 years (29,032 days).
Specimen C3L-06427-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Foot; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 04f2fb75-7723-4d8d-832d-dfd7e4497001.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06427-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/b73bafa1-f833-4883-ba5e-918b9baae55b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 669; copy number 2: 15,350; copy number 3: 20,314; copy number 4: 18,592; copy number 5: 1,410; copy number 6: 2,014; copy number 7: 5; copy number 8: 4; copy number 11: 26.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr8:12,064,389–12,175,771, 8 genes (within-gene range 0–2): DEFB130B, RNA5SP253, DEFB108D, ZNF705D, AC130366.1, USP17L7, USP17L2, FAM90A2P.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 35 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,461,221–144,068,350, 26 genes, copy number 11: AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D.
- chr7:79,768,028–80,312,456, 5 genes, copy number 7: GNAI1, RNU6-849P, RPL10P11, RN7SL869P, AC003988.1.
- chr8:40,298,697–40,897,833, 4 genes, copy number 8: SIRLNT, AC105999.1, AC010857.1, ZMAT4.

Autosomal genes at a single copy (total copy number 1): 669. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
